Gene-level copy-number profile of tumor specimen TCGA-UW-A72T-01A from TCGA case TCGA-UW-A72T, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.5 years (20,985 days).
Specimen TCGA-UW-A72T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c2ee0b3-5151-474a-93f3-4f0c0a1fdcbf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/e892a1a9-f1c8-446b-90f6-981f214f6de5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 130; copy number 2: 31,575; copy number 3: 2,568; copy number 4: 24,062; copy number 5: 36; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr9:61,190,003–61,662,690, 11 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:64,369,394–64,440,180, 3 genes: ANKRD20A4P, RNU6-1193P, SNX18P9.
- chr10:87,201,647–87,370,695, 6 genes (within-gene range 0–2): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D.
- chr17:36,165,681–36,176,636, 1 gene (within-gene range 0–2): TBC1D3B.
- chr17:36,210,924–36,334,759, 8 genes (within-gene range 0–2): CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–52,097,299, 17 genes, copy number 5: AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18.
- chr7:149,881,359–150,076,655, 7 genes, copy number 5: AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2.
- chr8:7,926,337–7,952,413, 2 genes, copy number 6: ZNF705B, DEFB108A.
- chr15:101,903,154–101,979,093, 10 genes, copy number 5: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:16,499,533–16,664,135, 2 genes, copy number 5: AC136431.1, AC136619.2.

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
